Somatic mutation profile of tumor specimen C3N-00753-01 (aliquot CPT0129640006) from CPTAC case C3N-00753, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G3.
Specimen C3N-00753-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73aea6d0-8bb7-4d8a-99e8-ab9a0998fb5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00753-31 (Blood Derived Normal), aliquot CPT0130880002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c387cf1-974d-451c-9076-2cd7106e8385

The open-access MAF lists 2,263 somatic variants for this specimen: 1,510 protein-altering or splice-affecting, 483 silent, 270 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,073, Silent 483, Frame Shift Del 260, Intron 151, Frame Shift Ins 52, Splice Site 42, 3'UTR 35, 5'UTR 34, Nonsense Mutation 34, Splice Region 28, RNA 25, In Frame Del 19.

Variants (750 of 2,263; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224958, CM040389, COSV58819321; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 30/220 reads (14%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- EPG5 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 38/365 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs1135402736, COSV99958016; ClinVar: pathogenic; called by muse, mutect2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 20/157 reads (13%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel
- MC2R | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs139218324, CM116421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.1865T>C p.L622P | Missense Mutation (SNP) | VAF 56/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs63750693, CM013002, CM122673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MOCS2 | c.65dup p.L23Ifs*5 | Frame Shift Ins (INS) | VAF 25/220 reads (11%) | catalogued as rs398122799; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 26/99 reads (26%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3312del p.F1104Lfs*11 | Frame Shift Del (DEL) | VAF 40/372 reads (11%) | catalogued as rs267608092; ClinVar: not provided / pathogenic; called by pindel, varscan2
- MYC | c.131C>T p.A44V (on ENST00000377970; = p.A59V on NM_002467.6) | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775522201, COSV52367462, COSV99422212; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 26/247 reads (11%) | catalogued as rs587784096, CM032971, COSV61771074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 29/247 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519946, COSV59042187, COSV59042498; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.437del p.L146* | Frame Shift Del (DEL) | VAF 36/235 reads (15%) | hotspot (GDC flag); catalogued as rs1114167627, COSV64292458; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SCN4A | c.3877G>A p.V1293I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs121908551, CM951140, COSV71126520; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SCN8A | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs796053233, COSV61993363; ClinVar: likely pathogenic; called by muse, mutect2
- SLC25A13 | c.70-1G>A p.X24_splice | Splice Site (SNP) | VAF 8/146 reads (5%) | catalogued as rs962082210; ClinVar: pathogenic; called by muse, mutect2
- SLC46A1 | c.194del p.G65Afs*25 | Frame Shift Del (DEL) | VAF 23/190 reads (12%) | catalogued as rs80338769, CD073700; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA13 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 40/205 reads (20%) | catalogued as COSV70025581; called by muse, mutect2, varscan2
- ABCA8 | c.2404C>T p.R802* | Nonsense Mutation (SNP) | VAF 60/379 reads (16%) | catalogued as rs201738885; called by muse, mutect2, varscan2
- ABCA8 | c.1745_1746del p.F582Cfs*2 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | catalogued as rs1475852997; called by mutect2, pindel, varscan2
- ABCB8 | c.701C>T p.S234F (on ENST00000297504 / NM_001282291.2; = p.S217F on NM_007188.5) | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99874538; called by muse, mutect2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | catalogued as rs749943218; called by mutect2, varscan2
- ABI2 | c.640G>A p.V214I (on ENST00000295851 / NM_001375719.1; = p.V208I on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV99651495; called by muse, mutect2, varscan2
- ABLIM2 | c.354del p.D120Tfs*3 | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | catalogued as rs749606695; called by mutect2, varscan2
- ACAP3 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs369571322; called by muse, mutect2, varscan2
- ACO2 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs755024692; called by muse, varscan2
- ACOT2 | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 133/955 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs756249281; called by muse, mutect2, varscan2
- ACTL7A | c.67dup p.L23Pfs*34 | Frame Shift Ins (INS) | VAF 15/139 reads (11%) | catalogued as rs771019158; called by mutect2, pindel, varscan2
- ADAM8 | c.875+1G>A p.X292_splice | Splice Site (SNP) | VAF 12/62 reads (19%) | catalogued as COSV101291634; called by muse, mutect2, varscan2
- ADAMTSL2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 97/700 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242674081, COSV63204290; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1907G>A p.R636H | Missense Mutation (SNP) | VAF 54/422 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV63203093; called by muse, varscan2
- ADARB2 | c.1908del p.F637Sfs*3 | Frame Shift Del (DEL) | VAF 43/280 reads (15%) | catalogued as COSV101184579; called by mutect2, pindel, varscan2
- ADGRG1 | c.843del p.S281Rfs*42 | Frame Shift Del (DEL) | VAF 54/464 reads (12%) | catalogued as COSV65636865; called by mutect2, pindel, varscan2
- ADGRV1 | c.5201A>T p.E1734V | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780537273; called by muse, mutect2, varscan2
- ADNP | c.3047dup p.A1017Gfs*6 | Frame Shift Ins (INS) | VAF 62/278 reads (22%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP2 | c.971del p.P324Lfs*8 | Frame Shift Del (DEL) | VAF 36/218 reads (17%) | catalogued as rs772825390; called by mutect2, varscan2
- AGRN | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as rs756579775; called by muse, mutect2, varscan2
- AJM1 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 63/338 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778041533, COSV56032636; called by muse, mutect2, varscan2
- AK3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs953055512; called by muse, mutect2
- AKAP11 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367790495; called by muse, mutect2
- ALAD | c.683del p.P228Lfs*24 | Frame Shift Del (DEL) | VAF 76/549 reads (14%) | catalogued as rs1564369378; called by mutect2, pindel, varscan2
- ALG5 | c.88A>G p.T30A | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs779974613; called by muse, mutect2, varscan2
- ALOX15 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs1221026723, COSV53396193; called by muse, mutect2, varscan2
- ANKLE1 | c.69del p.E24Sfs*54 | Frame Shift Del (DEL) | VAF 45/313 reads (14%) | catalogued as rs139615873; called by mutect2, pindel, varscan2
- ANKRD1 | c.668T>A p.L223Q | Missense Mutation (SNP) | VAF 107/770 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415797604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.4244A>C p.E1415A | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs756014125; called by muse, mutect2, varscan2
- ANKRD29 | c.531C>T p.D177= | Splice Region (SNP) | VAF 32/234 reads (14%) | catalogued as COSV99409104; called by muse, mutect2, varscan2
- ANO3 | c.2729T>G p.L910R | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99884865; called by muse, mutect2, varscan2
- AP1M1 | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766864704; called by muse, mutect2, varscan2
- APLNR | c.365G>C p.G122A | Missense Mutation (SNP) | VAF 44/400 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV99951310; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 33/236 reads (14%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP27 | c.2327G>A p.R776Q (on ENST00000428638 / NM_001282290.1; = p.R435Q on NM_199282.3) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65357347; called by muse, mutect2
- ARHGEF2 | c.286G>A p.A96T (on ENST00000361247 / NM_001162383.2; = p.A69T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1306042222; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 36/369 reads (10%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARL4D | c.237dup p.Q80Afs*28 | Frame Shift Ins (INS) | VAF 46/394 reads (12%) | catalogued as rs758198899; called by mutect2, pindel, varscan2
- ARSJ | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs1158899244; called by muse, mutect2, varscan2
- ARVCF | c.2605G>C p.D869H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52891237; called by muse, mutect2, varscan2
- ASAH2B | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 45/438 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as rs141006980; called by muse, mutect2, varscan2
- ASB14 | c.461_463del p.P154del (on ENST00000389601; = p.P153del on NM_001142733.3) | In Frame Del (DEL) | VAF 13/112 reads (12%) | catalogued as rs560364634; called by pindel, varscan2
- ASIC5 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770336848; called by muse, mutect2, varscan2
- ASPSCR1 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs558896726, COSV60727816; called by muse, mutect2, varscan2
- ATG2A | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 44/361 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1167250377; called by muse, mutect2, varscan2
- ATP10D | c.1786A>G p.T596A | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759295483; called by muse, mutect2, varscan2
- ATP2A3 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs745362732, COSV99989019; called by muse, mutect2, varscan2
- ATP2B2 | c.2572C>T p.R858C (on ENST00000352432; = p.R824C on NM_001683.5) | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1559538483; called by muse, mutect2
- ATP7B | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 116/712 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374592960; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AZU1 | c.483del p.R162Vfs*11 | Frame Shift Del (DEL) | VAF 36/212 reads (17%) | catalogued as rs772652509, COSV99297150; called by mutect2, pindel, varscan2
- B3GALT6 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 23/237 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs371901984; called by muse, mutect2
- BACE2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1396519038; called by muse, mutect2, varscan2
- BARHL2 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as rs751177593, COSV100966120; called by muse, varscan2
- BDH1 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746191768; called by muse, mutect2
- BHMT2 | c.336del p.I113Sfs*24 | Frame Shift Del (DEL) | VAF 14/141 reads (10%) | catalogued as rs36116756; called by mutect2, pindel, varscan2
- BOC | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56347107; called by muse, mutect2, varscan2
- BPNT1 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs772436104, COSV59041683; called by muse, mutect2
- BRINP3 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66542570; called by muse, mutect2, varscan2
- BRSK2 | c.1817G>A p.G606D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV100373158, COSV57546928; called by muse, mutect2, varscan2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs1455506786, COSV59000653; called by mutect2, pindel, varscan2
- BRWD3 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs777162950, COSV64745464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.9857G>T p.R3286I | Missense Mutation (SNP) | VAF 46/415 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99608407; called by muse, mutect2, varscan2
- BTBD16 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199722976; called by muse, mutect2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs751388819; called by mutect2, varscan2
- C15orf39 | c.2117T>C p.L706P | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1242469478; called by muse, mutect2
- C1QL4 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 34/672 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV57745010, COSV57745265; called by muse, mutect2
- C1S | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 44/466 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs782586778; called by muse, mutect2
- C1orf56 | c.474del p.R160Gfs*13 | Frame Shift Del (DEL) | VAF 31/244 reads (13%) | catalogued as rs761344402; called by mutect2, pindel, varscan2
- C22orf23 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs776578637, COSV50778083; called by muse, mutect2
- C22orf31 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 47/489 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs765154355, COSV53310375, COSV53310722; called by muse, mutect2, varscan2
- C4A | c.3442G>A p.A1148T | Missense Mutation (SNP) | VAF 60/743 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs767169624, COSV71179250; called by muse, mutect2, varscan2
- C5orf38 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 32/239 reads (13%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1417404093, COSV57413102; called by muse, mutect2, varscan2
- CA2 | c.440del p.L147* | Frame Shift Del (DEL) | VAF 66/495 reads (13%) | catalogued as rs763603775; called by mutect2, pindel, varscan2
- CACNA1B | c.6394C>T p.R2132C | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs952939628; called by muse, mutect2, varscan2
- CACNA1C | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as rs762756712, COSV59753249; called by muse, varscan2
- CAD | c.5792A>G p.Q1931R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53028933; called by muse, mutect2, varscan2
- CAMSAP1 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1049080690, COSV100409513; called by muse, mutect2
- CARD9 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs907791516, COSV53732249; called by muse, mutect2
- CBFA2T3 | c.1052A>G p.H351R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.854); catalogued as rs957469989; called by muse, mutect2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 23/183 reads (13%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CCDC102B | c.926del p.N309Mfs*2 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs1468612221; called by mutect2, varscan2
- CCDC27 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs560903163, COSV53899839; called by muse, mutect2, varscan2
- CCDC80 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs780582420, COSV52817562; called by muse, mutect2, varscan2
- CCDC88A | c.2032del p.T678Hfs*8 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV55059487; called by mutect2, varscan2
- CCN4 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs34782842; called by muse, mutect2
- CCNP | c.443A>G p.H148R | Missense Mutation (SNP) | VAF 62/502 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.042); catalogued as rs1568501683; called by muse, mutect2, varscan2
- CDC25B | c.1387G>A p.A463T (on ENST00000245960 / NM_021873.3; = p.A449T on NM_004358.4) | Missense Mutation (SNP) | VAF 44/293 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs1439228793, COSV55655060; called by muse, mutect2, varscan2
- CDC42EP4 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs772427276, COSV100232047; called by muse, mutect2, varscan2
- CDC45 | c.1532del p.P511Qfs*36 | Frame Shift Del (DEL) | VAF 49/383 reads (13%) | catalogued as rs1428199596, COSV54245063; called by mutect2, pindel, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 34/230 reads (15%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH23 | c.5675C>T p.A1892V | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs370004432; called by muse, mutect2
- CDK12 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212731319, COSV101420215; called by muse, mutect2, varscan2
- CDK5RAP1 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1243183648; called by muse, mutect2, varscan2
- CEACAM5 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.912); catalogued as rs1555814633; called by muse, mutect2
- CELSR1 | c.5758G>T p.G1920W | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV53091320; called by muse, mutect2
- CELSR2 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1473462904, COSV54770578; called by muse, mutect2, varscan2
- CENPB | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.312); catalogued as rs1369467816; called by muse, mutect2, varscan2
- CENPC | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 52/339 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747271436; called by muse, mutect2, varscan2
- CEP128 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374700489, COSV53673641; called by muse, mutect2
- CFP | c.1244+1G>A p.X415_splice | Splice Site (SNP) | VAF 52/375 reads (14%) | catalogued as rs1178102878; called by muse, mutect2, varscan2
- CHD4 | c.2936G>A p.R979Q (on ENST00000357008 / NM_001363606.2; = p.R992Q on NM_001273.5) | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58900604; called by muse, mutect2, varscan2
- CHMP1B | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV52327511; called by muse, mutect2, varscan2
- CHST15 | c.1192T>C p.L398= | Splice Region (SNP) | VAF 16/110 reads (15%) | catalogued as COSV100655041; called by muse, varscan2
- CHST3 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 84/534 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs772288774, COSV100910453; called by muse, mutect2, varscan2
- CHST3 | c.*5del | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | catalogued as rs1206428357; called by mutect2, pindel, varscan2
- CHST4 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV58296957; called by muse, mutect2, varscan2
- CIITA | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs760864976; called by muse, mutect2, varscan2
- CLASP1 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs1268867723, COSV55346666; called by muse, mutect2
- CLCA1 | c.1861A>G p.I621V | Missense Mutation (SNP) | VAF 57/457 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.371); catalogued as rs760339716; called by muse, mutect2, varscan2
- CLCNKB | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs762613611; called by muse, mutect2, varscan2
- CLDN10 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as rs776122725; called by muse, mutect2, varscan2
- CLTCL1 | c.296T>C p.M99T | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1555971483; called by muse, mutect2
- CNNM1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1320636081, COSV63203132; called by muse, mutect2, varscan2
- COL11A1 | c.2142del p.G715Dfs*50 | Frame Shift Del (DEL) | VAF 27/253 reads (11%) | catalogued as COSV100617967; called by mutect2, pindel, varscan2
- COL16A1 | c.3707del p.P1236Lfs*77 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | catalogued as rs769033024; called by mutect2, varscan2
- COL5A1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs763650548, COSV100880078; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.3716A>C p.D1239A | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55082755; called by muse, mutect2
- CORIN | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 49/315 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs901895303; called by muse, mutect2, varscan2
- CORO7 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 66/431 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs1007056462; called by muse, mutect2, varscan2
- CPEB3 | c.188del p.P63Rfs*19 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs751359395; called by mutect2, pindel, varscan2
- CPSF1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554866754, COSV100574308; called by muse, mutect2, varscan2
- CRHBP | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778573715, COSV57187946; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF1R | c.2392G>T p.G798W | Missense Mutation (SNP) | VAF 36/321 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53841798; called by muse, mutect2, varscan2
- CTIF | c.1071+3A>G | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as rs1399449501, COSV56488339; called by muse, mutect2, varscan2
- CUBN | c.5149G>A p.V1717I | Missense Mutation (SNP) | VAF 76/636 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs769662282, COSV64712705; called by muse, mutect2, varscan2
- CYFIP2 | c.2719G>A p.V907I (on ENST00000616178 / NM_001291722.2; = p.V882I on NM_014376.4) | Missense Mutation (SNP) | VAF 27/436 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV56636886; called by muse, mutect2
- CYLC2 | c.975G>T p.K325N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100872362; called by muse, mutect2, varscan2
- CYP2W1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs760287935; called by muse, mutect2, varscan2
- DAAM2 | c.2860C>T p.P954S (on ENST00000274867 / NM_001201427.2; = p.P953S on NM_015345.3) | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as COSV51302119; called by muse, mutect2
- DCAF4L2 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV60476348; called by muse, mutect2, varscan2
- DCBLD2 | c.75del p.A26Pfs*52 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | catalogued as rs1264389751; called by mutect2, pindel
- DCTD | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs765269080; called by muse, mutect2
- DCTN1 | c.2278A>G p.M760V | Missense Mutation (SNP) | VAF 107/757 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.893); catalogued as rs754780894; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- DCTN2 | c.599del p.P200Qfs*32 (on ENST00000548249 / NM_001261413.2; = p.P205Qfs*32 on NM_006400.4) | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | catalogued as rs745744034; called by mutect2, pindel, varscan2
- DDX19B | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs756212726, COSV55365657; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs1424884917, COSV64836411; called by mutect2, pindel, varscan2
- DEFB118 | c.78del p.K26Nfs*19 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | catalogued as rs750510475, COSV53620107; called by mutect2, varscan2
- DGKQ | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 29/272 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs758123010, COSV56619899; called by muse, mutect2, varscan2
- DGKZ | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs766092714; called by muse, mutect2, varscan2
- DICER1 | c.4025G>A p.R1342H | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.13); catalogued as rs767166092, COSV100602175; called by muse, mutect2
- DISP2 | c.1330A>G p.K444E | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1566915844; called by muse, mutect2
- DLG5 | c.3850C>T p.R1284W | Missense Mutation (SNP) | VAF 41/322 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs147486538; called by muse, mutect2, varscan2
- DLGAP2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs375416274, COSV101422983, COSV70099599, COSV99073642; called by muse, mutect2
- DNAH10 | c.295C>T p.R99* (on ENST00000409039; = p.R38* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as rs747681752; called by muse, mutect2, varscan2
- DNAH11 | c.11497G>A p.A3833T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs1428968679, COSV60965070; called by muse, mutect2, varscan2
- DNAJC2 | c.1173-7del | Splice Region (DEL) | VAF 14/114 reads (12%) | catalogued as rs538091160; called by mutect2, varscan2
- DNM2 | c.2377dup p.L793Pfs*31 (on ENST00000355667 / NM_001005360.3; = p.L789Pfs*31 on NM_004945.3) | Frame Shift Ins (INS) | VAF 27/221 reads (12%) | catalogued as rs764391392, COSV53034926; called by mutect2, varscan2
- DNMBP | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60628478; called by muse, mutect2, varscan2
- DPEP3 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763559134; called by muse, mutect2, varscan2
- DRC7 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 66/444 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.386); catalogued as rs1279424490, COSV61054841; called by muse, mutect2, varscan2
- DSCAML1 | c.2749G>A p.A917T (on ENST00000321322; = p.A857T on NM_020693.4) | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.961); catalogued as rs199597664, COSV58392450; called by muse, mutect2, varscan2
- DSCAML1 | c.1675C>T p.R559* (on ENST00000321322; = p.R499* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 32/556 reads (6%) | catalogued as COSV58383007; called by muse, mutect2
- DSCC1 | c.965T>A p.I322K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100558394; called by mutect2, varscan2
- DTX3 | c.433del p.L145Cfs*51 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | catalogued as rs758962538; called by mutect2, pindel, varscan2
- DUOX1 | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs752966307; called by muse, mutect2, varscan2
- DZIP1 | c.2182G>A p.E728K (on ENST00000347108; = p.E709K on NM_014934.5) | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.277); catalogued as rs1444367378, COSV61264299; called by muse, mutect2
- E4F1 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs763870651; called by muse, mutect2, varscan2
- EEF1D | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs145281112; called by muse, mutect2
- EFHD1 | c.109A>G p.K37E | Missense Mutation (SNP) | VAF 21/347 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1011993822; called by muse, mutect2
- EGR3 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 79/353 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1205883514, COSV57834169; called by muse, mutect2, varscan2
- EML1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs748777777; called by muse, mutect2, varscan2
- EML6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs962097491, COSV62866515; called by muse, mutect2, varscan2
- ENGASE | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs758339425, COSV100285907; called by muse, mutect2, varscan2
- ENO4 | c.1029del p.H345Tfs*21 (on ENST00000622726; = p.H342Tfs*21 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 63/489 reads (13%) | catalogued as rs1156693659; called by mutect2, pindel, varscan2
- EPB41L4A | c.885del p.F295Lfs*35 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as rs1157347372; called by mutect2, pindel, varscan2
- EPG5 | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776940588, COSV56352112; called by muse, mutect2, varscan2
- ERAL1 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs540938776; called by muse, mutect2
- ERCC3 | c.777A>T p.E259D | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs772883177, COSV53425973; called by muse, mutect2
- ERCC6 | c.972del p.E325Rfs*4 | Frame Shift Del (DEL) | VAF 53/534 reads (10%) | catalogued as COSV63390409; called by mutect2, pindel, varscan2
- ERGIC1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as rs777001809, COSV67127686; called by muse, mutect2, varscan2
- ERN2 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 128/654 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.06); catalogued as rs761777412, COSV56835416, COSV56836319; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 88/300 reads (29%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC | c.2794A>G p.R932G | Missense Mutation (SNP) | VAF 103/600 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV99382604; called by muse, mutect2, varscan2
- EVPL | c.5404G>A p.A1802T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs368022111, COSV56914083; called by muse, mutect2, varscan2
- EXOC6 | c.891T>C p.G297= | Splice Region (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53324161; called by muse, mutect2, varscan2
- EXOSC6 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1357385663; called by muse, mutect2, varscan2
- EXTL3 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 51/508 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs779822953; called by muse, mutect2
- FAM111B | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs374133736; called by muse, mutect2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 40/282 reads (14%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM50B | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 56/468 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66654701; called by muse, mutect2, varscan2
- FAM83B | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as rs147775708, COSV60921364; called by muse, varscan2
- FANCC | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 59/423 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs373270404; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASTKD1 | c.655_657del p.L219del | In Frame Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs757208851; called by pindel, varscan2
- FAT1 | c.13360G>A p.E4454K | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs367799188; called by muse, mutect2, varscan2
- FAT1 | c.4435A>G p.S1479G | Missense Mutation (SNP) | VAF 51/352 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as rs1488643723; called by muse, mutect2, varscan2
- FAT3 | c.12838G>A p.V4280M | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53110551; called by muse, mutect2, varscan2
- FBN1 | c.619del p.T207Rfs*123 | Frame Shift Del (DEL) | VAF 45/405 reads (11%) | catalogued as CD067548; called by mutect2, pindel, varscan2
- FCHO1 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.917); catalogued as rs753883103; called by muse, mutect2, varscan2
- FCN1 | c.904A>G p.N302D | Missense Mutation (SNP) | VAF 80/562 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as rs1342400949; called by muse, mutect2, varscan2
- FEZ2 | c.854del p.N285Mfs*19 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | catalogued as rs772264399; called by mutect2, pindel, varscan2
- FGD4 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 43/303 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs989576032, COSV56780605; called by muse, mutect2, varscan2
- FGFRL1 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466236583; called by muse, mutect2, varscan2
- FH | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as COSV63818301; called by muse, mutect2, varscan2
- FLNC | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 109/635 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs752919962, COSV57951820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3LG | c.676A>G p.S226G | Missense Mutation (SNP) | VAF 34/283 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV99201302; called by muse, mutect2, varscan2
- FNDC1 | c.1573C>T p.L525F | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV51933758; called by muse, mutect2, varscan2
- FNIP2 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 39/309 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs751093209, COSV52442459; called by muse, mutect2, varscan2
- FOXP4 | c.1391C>T p.A464V (on ENST00000307972 / NM_001012426.1; = p.A451V on NM_138457.3) | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57220047; called by muse, mutect2, varscan2
- FRA10AC1 | c.76del p.R26Gfs*44 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs755202796; called by mutect2, pindel
- FSTL5 | c.225C>G p.H75Q | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.779); catalogued as COSV60207532; called by muse, mutect2, varscan2
- FUBP3 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1271251654; called by muse, mutect2, varscan2
- GABRA6 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 49/405 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs377498858; called by muse, mutect2, varscan2
- GALM | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1362939369; called by muse, mutect2
- GAS7 | c.1157G>C p.C386S (on ENST00000432992 / NM_201433.2; = p.C246S on NM_003644.3) | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs1189933712; called by muse, mutect2
- GEM | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 54/670 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs149283301; called by muse, mutect2
- GEMIN5 | c.3185del p.K1062Rfs*17 | Frame Shift Del (DEL) | VAF 61/515 reads (12%) | catalogued as COSV53560004; called by mutect2, pindel, varscan2
- GGN | c.809del p.G270Afs*20 | Frame Shift Del (DEL) | VAF 75/469 reads (16%) | catalogued as COSV53057105; called by mutect2, pindel, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as rs763147690; called by mutect2, varscan2
- GIPC3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs763093036, COSV59258954; called by muse, mutect2, varscan2
- GP5 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1269260949; called by muse, mutect2, varscan2
- GPATCH8 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 38/384 reads (10%) | catalogued as COSV59193546; called by muse, mutect2
- GPHB5 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs746805619; called by muse, mutect2, varscan2
- GPM6A | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1275306778, COSV54558734, COSV99702799; called by muse, mutect2, varscan2
- GRB10 | c.1381G>A p.A461T (on ENST00000398812; = p.A415T on NM_001001549.3) | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV60015419; called by muse, mutect2, varscan2
- GREB1L | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1297025222; called by muse, mutect2, varscan2
- GRIK4 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs758270994; called by muse, mutect2
- GRIP2 | c.2668G>A p.E890K (on ENST00000619221; = p.E793K on NM_001080423.4) | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs759811179, COSV56120637; called by muse, varscan2
- GRK6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs777094286, COSV62683395; called by muse, mutect2, varscan2
- GSDMD | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99369588; called by muse, mutect2, varscan2
- GTF3C1 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as rs763893267, COSV62241640; called by muse, mutect2, varscan2
- GULP1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.212); catalogued as rs369004912; called by muse, mutect2
- GYS2 | c.1414A>G p.R472G | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287028288; called by muse, mutect2, varscan2
- H2BC9 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.098); catalogued as rs1432232511, COSV99769149; called by muse, mutect2, varscan2
- H6PD | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 74/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202128149; called by muse, mutect2, varscan2
- HABP4 | c.1130del p.G377Efs*19 | Frame Shift Del (DEL) | VAF 39/210 reads (19%) | catalogued as COSV64515089; called by mutect2, varscan2
- HAPLN4 | c.743del p.G248Afs*31 | Frame Shift Del (DEL) | VAF 52/374 reads (14%) | catalogued as rs1382903742; called by mutect2, pindel, varscan2
- HCAR2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 82/499 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs766114637; called by muse, mutect2, varscan2
- HCST | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.56); catalogued as rs1479266066; called by muse, mutect2, varscan2
- HEATR9 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs750233470; called by muse, mutect2
- HECTD4 | c.13076C>T p.P4359L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1188443858, COSV66394616; called by muse, varscan2
- HECW2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1284621782, COSV53673584; called by muse, mutect2, varscan2
- HEPHL1 | c.1318A>G p.T440A | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as rs1458054694; called by muse, mutect2
- HERC1 | c.5634del p.V1879Lfs*26 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | catalogued as rs1287865515; called by mutect2, varscan2
- HERC1 | c.1178T>C p.I393T | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs756006394; called by muse, mutect2, varscan2
- HERC2 | c.5230C>T p.R1744* | Nonsense Mutation (SNP) | VAF 53/586 reads (9%) | catalogued as COSV55308761; called by muse, mutect2
- HERPUD1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.029); catalogued as rs1262881578; called by muse, mutect2, varscan2
- HIBCH | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as rs1248460683, COSV100675978; called by muse, mutect2, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | catalogued as rs751976368; called by mutect2, pindel
- HNF1A | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs373857078; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXD4 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 69/557 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); catalogued as COSV100106910, COSV60460270; called by muse, mutect2, varscan2
- HSPA12B | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs767401550; called by muse, mutect2
- HSPG2 | c.6260G>A p.R2087Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as rs141582415; called by muse, mutect2, varscan2
- HTR2B | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs761682358, COSV51448890; called by muse, mutect2, varscan2
- HTR6 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 73/615 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244776239, COSV99230163; called by muse, mutect2, varscan2
- HYAL1 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs142667148; called by muse, mutect2
- HYDIN | c.2057C>T p.A686V | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs199673743; called by muse, mutect2, varscan2
- ICA1L | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV64172555; called by muse, mutect2, varscan2
- ICA1L | c.111del p.E38Rfs*30 | Frame Shift Del (DEL) | VAF 21/192 reads (11%) | catalogued as rs1330717036; called by mutect2, pindel
- ICE1 | c.3740del p.N1247Ifs*17 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as COSV99664110; called by mutect2, pindel, varscan2
- IFITM5 | c.95del p.P32Rfs*6 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as rs774773661; called by mutect2, pindel, varscan2
- IGHA1 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 62/529 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs373374418; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 45/1066 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs370560002; called by muse, mutect2
- IGLV6-57 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 58/482 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.46); catalogued as rs375719682; called by muse, mutect2, varscan2
- IL1B | c.303A>G p.E101= | Splice Region (SNP) | VAF 32/368 reads (9%) | catalogued as rs752959492; called by muse, mutect2
- IL7R | c.876+12del | Splice Region (DEL) | VAF 42/336 reads (13%) | catalogued as rs777036777; called by mutect2, pindel, varscan2
- INAVA | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs868123316; called by muse, mutect2, varscan2
- INAVA | c.1730G>A p.G577D | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs776253775; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSM2 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51879466; called by muse, mutect2
- INTS5 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1230371945; called by muse, mutect2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQGAP3 | c.4684G>A p.V1562I | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs748373017; called by muse, mutect2, varscan2
- IQSEC1 | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as rs1201035554; called by muse, mutect2
- IRF6 | c.1052T>A p.F351Y | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1224922793; called by muse, mutect2, varscan2
- ITFG1 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567456332; called by muse, mutect2, varscan2
- ITGAD | c.1497+1del | Frame Shift Del (DEL) | VAF 10/113 reads (9%) | catalogued as rs762659181; called by mutect2, pindel
- ITPKB | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1399583186, COSV55259532; called by muse, mutect2, varscan2
- ITPR1 | c.5912G>A p.R1971H (on ENST00000354582; = p.R1916H on NM_002222.7) | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57008498; called by muse, mutect2, varscan2
- ITSN1 | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66084913; called by muse, mutect2, varscan2
- JADE2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 81/588 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs1405155291, COSV50914111; called by muse, mutect2, varscan2
- KCNC2 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs200051664, COSV54366403; called by muse, mutect2, varscan2
- KCND2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV58607195; called by muse, mutect2
- KCNIP4 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs149197141; called by muse, mutect2, varscan2
- KCNK3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867125322; called by muse, mutect2
- KCNS1 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 58/576 reads (10%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs764337507; called by muse, mutect2, varscan2
- KHDRBS3 | c.752del p.P251Qfs*101 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | catalogued as rs776179021, COSV63421003; called by mutect2, varscan2
- KHSRP | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV67920004; called by muse, mutect2, varscan2
- KIAA1549L | c.3257G>A p.R1086H (on ENST00000321505; = p.R1383H on NM_012194.3) | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs572642569, COSV55772555; called by muse, mutect2, varscan2
- KIAA2013 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100927156; called by muse, mutect2, varscan2
- KIAA2013 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 75/580 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as rs1435144168; called by muse, mutect2, varscan2
- KIF13B | c.4079G>A p.R1360H | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745847947, COSV72954715; called by muse, mutect2, varscan2
- KIF1A | c.4876G>A p.V1626M (on ENST00000320389 / NM_001379639.1; = p.V1618M on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as rs200511467; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- KIF1A | c.4808G>A p.R1603H (on ENST00000320389 / NM_001379639.1; = p.R1595H on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs756912340, COSV100240907, COSV100240915; ClinVar: uncertain significance; called by muse, varscan2
- KIFC3 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 64/352 reads (18%) | catalogued as rs1555622071; called by muse, mutect2, varscan2
- KLHL33 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 33/286 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs543380954, COSV60725668; called by muse, mutect2, varscan2
- KLRC2 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 45/802 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1432797801, COSV67899859; called by muse, mutect2
- KMT2D | c.14470G>A p.A4824T | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs759709365; called by muse, mutect2
- KRBA2 | c.919A>G p.S307G | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.247); catalogued as rs1000225855; called by muse, mutect2, varscan2
- KRT17 | c.161del p.G54Vfs*61 | Frame Shift Del (DEL) | VAF 75/700 reads (11%) | catalogued as rs761469971; called by mutect2, pindel, varscan2
- KRT73 | c.1612del p.T538Pfs*2 | Frame Shift Del (DEL) | VAF 8/69 reads (12%) | catalogued as rs747582553; called by mutect2, pindel, varscan2
- KRTAP10-1 | c.282del p.C95Afs*233 | Frame Shift Del (DEL) | VAF 115/1000 reads (12%) | catalogued as COSV59961454; called by mutect2, pindel, varscan2
- LAMA3 | c.9127C>T p.R3043C (on ENST00000313654 / NM_198129.4; = p.R1434C on NM_000227.6) | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs778826328, COSV99334386; called by muse, mutect2, varscan2
- LAMB1 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753663712; called by muse, mutect2
- LAMB4 | c.26del p.L9Cfs*43 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs747409331; called by pindel, varscan2
- LLGL1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372430699; called by muse, mutect2, varscan2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 28/245 reads (11%) | catalogued as rs765428971; called by mutect2, pindel, varscan2
- LPCAT1 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52041445; called by muse, mutect2
- LRBA | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV100841204; called by muse, mutect2
- LRP1 | c.13598G>A p.R4533Q | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1031302605, COSV99675881; called by muse, mutect2, varscan2
- LRRC36 | c.1267A>C p.S423R | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as COSV99339311; called by muse, mutect2, varscan2
- LTBP3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 28/532 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs750231928; called by muse, mutect2
- LTK | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs55683312, COSV53028509; called by muse, mutect2, varscan2
- M1AP | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs748173359, COSV51844163, COSV51844688; called by muse, mutect2, varscan2
- MACF1 | c.20131C>T p.R6711* (on ENST00000372915; = p.R4756* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as rs1475835927; called by muse, mutect2
- MACF1 | c.21482G>A p.R7161H (on ENST00000372915; = p.R5206H on NM_012090.5) | Missense Mutation (SNP) | VAF 29/234 reads (12%) | catalogued as rs1357991791; called by muse, mutect2, varscan2
- MAFG | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as rs369590280; called by muse, mutect2, varscan2
- MAGEE2 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.861); catalogued as COSV64897778, COSV64897940, COSV64898394; called by muse, mutect2, varscan2
- MAML2 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1249222306, COSV101594071; called by muse, mutect2, varscan2
- MAN1B1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 36/737 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs1032317403, COSV65371104; called by muse, mutect2
- MAN1C1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs1458744212, COSV104381513; called by muse, mutect2
- MAP3K1 | c.1423+2T>C p.X475_splice | Splice Site (SNP) | VAF 56/403 reads (14%) | catalogued as rs1257948934, COSV68122860; called by muse, mutect2, varscan2
- MAP3K19 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | catalogued as COSV59642269; called by muse, mutect2, varscan2
- MAP3K4 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62338721; called by muse, mutect2, varscan2
- MAP3K6 | c.2544del p.F849Sfs*143 | Frame Shift Del (DEL) | VAF 31/250 reads (12%) | catalogued as rs34008139, CD1410625; called by mutect2, pindel, varscan2
- MAPK4 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.121); catalogued as COSV101245390; called by muse, mutect2, varscan2
- MBD1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99496418; called by muse, mutect2
- MCC | c.2062G>A p.G688S | Missense Mutation (SNP) | VAF 49/379 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs141601030; called by muse, mutect2, varscan2
- MCEMP1 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100365439; called by muse, mutect2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs750092100; called by mutect2, varscan2
- MED24 | c.2109dup p.K704Qfs*30 | Frame Shift Ins (INS) | VAF 29/275 reads (11%) | catalogued as rs746303506; called by mutect2, pindel, varscan2
- MEFV | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as COSV54824037, COSV99561255; called by muse, mutect2
- MEGF8 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs972539405, COSV52099788; called by muse, mutect2, varscan2
- MEGF8 | c.5858G>A p.R1953H (on ENST00000251268 / NM_001271938.2; = p.R1886H on NM_001410.3) | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.661); catalogued as rs771233244, COSV52075498; called by muse, mutect2, varscan2
- METTL3 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52968434; called by muse, mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 22/158 reads (14%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD6 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.318); catalogued as rs760269189, COSV99855005, COSV99855363; called by muse, mutect2, varscan2
- MGST3 | c.310T>G p.Y104D | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63321639; called by muse, mutect2, varscan2
- MICALL2 | c.1715T>C p.M572T | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773222447, COSV52516091; called by muse, mutect2, varscan2
- MICU1 | c.191A>G p.D64G | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.005); catalogued as rs1426796562; called by muse, mutect2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 39/264 reads (15%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs751180035; called by mutect2, varscan2
- MKI67 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766987700, COSV64073124; called by muse, mutect2, varscan2
- MKRN2 | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1303067523; called by muse, mutect2
- MLH1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607727, CM033398, COSV51626599, COSV99212305; called by muse, mutect2, varscan2
- MLXIP | c.2042G>A p.C681Y | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.34); catalogued as COSV59837178; called by muse, mutect2, varscan2
- MMAA | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs148142853; called by muse, mutect2, varscan2
- MMEL1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 51/380 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as rs745908222, COSV56525111; called by muse, mutect2, varscan2
- MMP20 | c.93del p.R32Gfs*37 | Frame Shift Del (DEL) | VAF 63/514 reads (12%) | catalogued as COSV99497522; called by pindel, varscan2
- MMP26 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100332221; called by muse, mutect2, varscan2
- MOGS | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs370469058, COSV99270351; called by muse, mutect2
- MPDU1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 81/588 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1396777488; called by muse, mutect2, varscan2
- MRTFA | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs199908950, COSV62932756; called by muse, mutect2, varscan2
- MSLN | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs371487653, COSV99558619; called by muse, mutect2, varscan2
- MST1 | c.2126C>T p.T709M | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1409047630; called by muse, mutect2, varscan2
- MTBP | c.34del p.E12Kfs*39 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as rs1563780092; called by mutect2, pindel, varscan2
- MTG2 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV63693780; called by muse, mutect2, varscan2
- MTM1 | c.592T>A p.Y198N | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM970988, CP973605; called by muse, mutect2, varscan2
- MTMR3 | c.1813del p.L605* | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | catalogued as COSV60305229; called by mutect2, pindel, varscan2
- MTNR1B | c.800T>C p.L267P | Missense Mutation (SNP) | VAF 68/517 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1351767862; called by muse, mutect2, varscan2
- MTX1 | c.22del p.R8Afs*110 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs755845788, COSV57426587; called by mutect2, varscan2
- MUC12 | c.5860C>G p.P1954A (on ENST00000379442; = p.P1811A on NM_001164462.1) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.55); catalogued as rs111685361, COSV65188428; called by mutect2, varscan2
- MUC12 | c.15074C>G p.P5025R (on ENST00000379442; = p.P4882R on NM_001164462.1) | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated, low confidence (0.12); catalogued as rs1165363579; called by muse, mutect2, varscan2
- MUC16 | c.36692C>A p.P12231Q | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as COSV67477851; called by muse, mutect2, varscan2
- MUC3A | c.940del p.L314Yfs*5 | Frame Shift Del (DEL) | VAF 34/212 reads (16%) | catalogued as COSV60222562; called by mutect2, pindel, varscan2
- MUC4 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs752700892, COSV100638805; called by mutect2, varscan2
- MUC5B | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs367802099; called by muse, mutect2
- MX2 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.921); catalogued as rs1170842674, COSV58095013; called by muse, mutect2
- MXD1 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs770685645; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 46/245 reads (19%) | catalogued as rs764857791; called by mutect2, varscan2
- MYBL1 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV72918741; called by muse, mutect2
- MYF6 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99952962; called by muse, mutect2, varscan2
- MYH2 | c.1489T>C p.F497L | Missense Mutation (SNP) | VAF 69/754 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1226633698; called by muse, mutect2
- MYH7 | c.4518G>T p.Q1506H | Missense Mutation (SNP) | VAF 74/516 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1381038165; called by muse, mutect2, varscan2
- MYO16 | c.4901A>G p.K1634R | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); catalogued as rs989634782; called by muse, mutect2, varscan2
- MYO1C | c.1787G>A p.R596Q (on ENST00000648651 / NM_001080779.2; = p.R561Q on NM_033375.5) | Missense Mutation (SNP) | VAF 59/495 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs372299065; called by muse, mutect2, varscan2
- MYO1G | c.2219T>C p.M740T | Missense Mutation (SNP) | VAF 70/560 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs905006130; called by muse, mutect2, varscan2
- MYT1L | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.059); catalogued as rs1203413211; called by muse, mutect2, varscan2
- MZF1 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as rs900246136; called by muse, mutect2, varscan2
- NAGLU | c.2186_2188del p.K729del | In Frame Del (DEL) | VAF 58/458 reads (13%) | catalogued as rs1216052074; called by pindel, varscan2
- NANOGNB | c.242dup p.N81Kfs*8 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs1455893486; called by mutect2, varscan2
- NAPRT | c.1475_1476del p.E492Vfs*2 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as rs751400192; called by pindel, varscan2
- NBEA | c.7741G>T p.D2581Y | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100085094; called by muse, mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 58/429 reads (14%) | catalogued as rs772347389; called by mutect2, varscan2
- NDNF | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs758373774, COSV65633908; called by muse, mutect2, varscan2
- NDOR1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs772563223; called by muse, mutect2, varscan2
- NKX6-3 | c.182G>T p.R61M | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs191236279; called by muse, mutect2, varscan2
- NLRC5 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52659159; called by muse, mutect2, varscan2
- NLRP13 | c.1610T>C p.L537P | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs1055227156; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 22/129 reads (17%) | catalogued as rs746543323; called by mutect2, pindel, varscan2
- NOTCH4 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 74/580 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100900876; called by muse, mutect2, varscan2
- NOX5 | c.1807A>G p.I603V | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs546652219, COSV52987641; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 29/255 reads (11%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NPL | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs185002399; called by muse, mutect2, varscan2
- NRROS | c.1492del p.V498Ffs*2 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | catalogued as rs1560057016; called by mutect2, pindel, varscan2
- NSD2 | c.3766C>A p.R1256S | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV56395137; called by muse, mutect2
- NUBP1 | c.518del p.P173Hfs*24 | Frame Shift Del (DEL) | VAF 30/260 reads (12%) | catalogued as rs1184874826; called by mutect2, pindel, varscan2
- NUMB | c.874C>T p.R292C (on ENST00000355058; = p.R281C on NM_003744.5) | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774508876, COSV61828103; called by muse, mutect2, varscan2
- NXPE1 | c.1531G>A p.V511M (on ENST00000424269; = p.V369M on NM_152315.5) | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs762117458; called by muse, mutect2
- NYNRIN | c.4700G>A p.R1567H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769142864, COSV66844901; called by muse, varscan2
- OBSCN | c.23002A>G p.S7668G | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1007728935; called by muse, mutect2, varscan2
- OIT3 | c.916C>A p.L306I | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1171552605; called by muse, mutect2
- OPLAH | c.3643G>A p.G1215S | Missense Mutation (SNP) | VAF 48/479 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781820783, COSV101085294; called by muse, mutect2, varscan2
- OPLAH | c.3319G>A p.V1107M | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs1212221272, COSV70677638; called by muse, mutect2, varscan2
- OR4C11 | c.779del p.P260Rfs*28 | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs764963140, COSV56352663, COSV56353360; called by mutect2, pindel, varscan2
- OR4D1 | c.342dup p.L115Sfs*7 | Frame Shift Ins (INS) | VAF 42/337 reads (12%) | catalogued as rs752664388; called by mutect2, pindel, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 70/588 reads (12%) | catalogued as rs1566497842; called by mutect2, pindel, varscan2
- OR52A5 | c.194del p.L65Wfs*20 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | catalogued as rs762677866, COSV100263457; called by mutect2, pindel, varscan2
- OR56A1 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs751508543; called by mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 14/111 reads (13%) | catalogued as rs747074822; called by mutect2, varscan2
- PAH | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 79/636 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as CM071056, COSV61016525; called by muse, mutect2, varscan2
- PANK4 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 44/302 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs1430318759; called by muse, mutect2, varscan2
- PAX1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 98/881 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as rs763110376; called by muse, mutect2, varscan2
- PCDH17 | c.2944G>A p.V982I | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as rs771241451, COSV100932174; called by muse, mutect2, varscan2
- PCDH8 | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777231257; called by muse, mutect2, varscan2
- PCDHA8 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 66/848 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV65341118; called by muse, mutect2
- PCDHB15 | c.1454A>G p.Q485R | Missense Mutation (SNP) | VAF 26/756 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.05); catalogued as rs1554292089; called by muse, mutect2
- PCDHB15 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 150/933 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); catalogued as rs868929992, COSV50867243; called by mutect2, varscan2
- PCDHB3 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 156/1002 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.022); catalogued as rs138158842; called by muse, varscan2
- PCDHB7 | c.1609G>A p.G537S | Missense Mutation (SNP) | VAF 154/1208 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs370593305; called by muse, mutect2, varscan2
- PCDHB8 | c.1391A>G p.N464S | Missense Mutation (SNP) | VAF 105/1669 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99177565; called by muse, mutect2
- PCDHGA10 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV54045051; called by muse, mutect2, varscan2
- PCDHGB2 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 64/597 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs748394772; called by muse, varscan2
- PCDHGB7 | c.1499C>T p.T500M | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs569760413, COSV99545134; called by muse, mutect2, varscan2
- PCNT | c.4180dup p.E1394Gfs*33 | Frame Shift Ins (INS) | VAF 32/277 reads (12%) | catalogued as rs755265991; called by mutect2, pindel, varscan2
- PCNX4 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs761997870; called by muse, mutect2
- PDCD1 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs763027752; called by muse, mutect2, varscan2
- PDE7B | c.932G>T p.R311M | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57503091; called by muse, mutect2, varscan2
- PDLIM7 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as rs146789460; called by muse, mutect2, varscan2
- PEPD | c.1134C>A p.D378E | Missense Mutation (SNP) | VAF 67/606 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV104390147; called by muse, mutect2, varscan2
- PER3 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as rs1445100478; called by muse, mutect2
- PGLYRP2 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 42/331 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs760383491; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs1163689977; called by mutect2, pindel
- PHLPP2 | c.3601T>C p.S1201P | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.036); catalogued as rs1444812076; called by muse, mutect2, varscan2
- PIGC | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1411201760; called by muse, mutect2, varscan2
- PITPNM1 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs1481653109; called by muse, mutect2, varscan2
- PLCD4 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747172541, COSV68842807; called by muse, mutect2, varscan2
- PLCH1 | c.3346T>G p.F1116V (on ENST00000340059 / NM_001130960.2; = p.F1108V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.006); catalogued as rs774940897; called by muse, mutect2, varscan2
- PLD2 | c.1738T>C p.Y580H | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV54006651; called by muse, mutect2
- PLD2 | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1272896307; called by muse, mutect2, varscan2
- PLEC | c.2023C>T p.R675C (on ENST00000322810 / NM_201380.4; = p.R565C on NM_000445.5) | Missense Mutation (SNP) | VAF 119/569 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs782678779, COSV100514295, COSV59676279; called by muse, mutect2, varscan2
- PLEKHA2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377170637; called by muse, mutect2, varscan2
- PLEKHA4 | c.2163del p.R722Dfs*114 | Frame Shift Del (DEL) | VAF 33/226 reads (15%) | catalogued as rs1475346166; called by mutect2, pindel, varscan2
- PLEKHG2 | c.3964dup p.Q1322Pfs*19 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs551236586; called by mutect2, varscan2
- PLIN4 | c.1402G>T p.G468W (on ENST00000301286; = p.G483W on NM_001367868.2) | Missense Mutation (SNP) | VAF 95/732 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014335; called by muse, mutect2, varscan2
- PLXNA1 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs766392082, COSV52526702; called by muse, mutect2, varscan2
- PLXNA1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 63/442 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.82); catalogued as rs545559492, COSV52525737; called by muse, mutect2, varscan2
- PMPCB | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs530790514, COSV50785599; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1524T>A p.N508K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1369989817, COSV100544197, COSV57969449; called by muse, mutect2, varscan2
- POMT2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs779190087; ClinVar: uncertain significance; called by muse, mutect2
- POR | c.516G>A p.A172= | Splice Region (SNP) | VAF 24/167 reads (14%) | catalogued as rs782798260, COSV101203551; called by muse, mutect2, varscan2
- POU3F3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 14/101 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs1305921545; called by muse, mutect2, varscan2
- POU3F3 | c.400del p.Q134Sfs*16 | Frame Shift Del (DEL) | VAF 14/98 reads (14%) | catalogued as rs1271589800; called by pindel, varscan2
- PPAN-P2RY11 | c.2003C>T p.A668V | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs142011996; called by muse, mutect2, varscan2
- PPARG | c.154G>A p.V52I (on ENST00000287820 / NM_015869.5; = p.V22I on NM_005037.7) | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as rs149324518; called by muse, mutect2, varscan2
- PPRC1 | c.3917dup p.M1309Dfs*47 | Frame Shift Ins (INS) | VAF 24/158 reads (15%) | catalogued as rs749215431; called by mutect2, varscan2
- PRCC | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs1294198270, COSV54857754; ClinVar: other; called by muse, mutect2, varscan2
- PRDM5 | c.1639T>C p.C547R | Missense Mutation (SNP) | VAF 63/553 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560932724; called by muse, mutect2, varscan2
- PROSER2 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs966446053; called by muse, mutect2, varscan2
- PROX1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1160303355; called by muse, mutect2, varscan2
- PRPS1L1 | c.317del p.P106Qfs*13 | Frame Shift Del (DEL) | VAF 45/278 reads (16%) | catalogued as COSV72649829; called by mutect2, pindel, varscan2
- PRR29 | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.917); catalogued as rs1312066532; called by muse, varscan2
- PRUNE2 | c.6524C>T p.A2175V | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV65038954; called by muse, mutect2, varscan2
- PTPRA | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs759898695; called by muse, mutect2, varscan2
- PTPRD | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs773166856; called by muse, mutect2, varscan2
- PTRH2 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs772335469; called by muse, mutect2, varscan2
- PXDN | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.733); catalogued as COSV53232473; called by muse, mutect2
- PXDNL | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.108); catalogued as rs1366134728, COSV62478619; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs372735637; called by muse, mutect2, varscan2
- RAB2A | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs1267298715; called by muse, mutect2, varscan2
- RAB8A | c.517del p.M173Wfs*49 | Frame Shift Del (DEL) | VAF 24/167 reads (14%) | catalogued as COSV53737226; called by mutect2, pindel, varscan2
- RAF1 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751232720, COSV50104098; called by muse, mutect2, varscan2
- RALGAPA2 | c.627C>A p.C209* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV99173132; called by muse, mutect2
- RANBP2 | c.3596C>T p.A1199V | Missense Mutation (SNP) | VAF 35/392 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.989); catalogued as rs138368821; called by muse, mutect2
- RAPGEF3 | c.1543C>T p.R515W (on ENST00000389212; = p.R473W on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377464139; called by muse, mutect2, varscan2
- RASAL3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 66/384 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99483810; called by muse, varscan2
- RBM43 | c.213del p.V72Lfs*13 | Frame Shift Del (DEL) | VAF 20/136 reads (15%) | catalogued as rs746242773; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBMXL2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs755396057; called by muse, mutect2
- RCSD1 | c.355C>T p.H119Y | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.335); catalogued as rs1309249570; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | catalogued as rs759247453; called by mutect2, varscan2
- RERE | c.452dup p.A152Sfs*16 | Frame Shift Ins (INS) | VAF 17/142 reads (12%) | catalogued as rs1233062866; called by mutect2, pindel, varscan2
- RFX7 | c.1261T>C p.S421P (on ENST00000559447 / NM_001368074.1; = p.S518P on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/494 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs1241506467; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs751982308; called by mutect2, varscan2
- RIPK4 | c.65T>A p.F22Y | Missense Mutation (SNP) | VAF 83/651 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60186936; called by muse, mutect2, varscan2
- RIPOR2 | c.2684G>A p.G895D | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.536); catalogued as rs1173363157; called by muse, mutect2, varscan2
- RNF123 | c.691A>G p.M231V | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs759833117; called by muse, mutect2
- RNF223 | c.694del p.R232Gfs*15 | Frame Shift Del (DEL) | VAF 40/214 reads (19%) | catalogued as rs771408178, COSV69251216; called by mutect2, varscan2
- RNF25 | c.749del p.G250Efs*29 | Frame Shift Del (DEL) | VAF 45/424 reads (11%) | catalogued as rs746813141; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 28/144 reads (19%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RNH1 | c.101+2T>C p.X34_splice | Splice Site (SNP) | VAF 29/266 reads (11%) | catalogued as rs762192949; called by muse, mutect2, varscan2
- ROR1 | c.1993A>G p.M665V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1182989456; called by muse, mutect2
- RPL3 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV53366825; called by muse, mutect2, varscan2
- RUFY1 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756420861, COSV60159556; called by muse, mutect2, varscan2
- RYR1 | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 109/826 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573649990, CM136213; called by muse, mutect2, varscan2
- S1PR1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs11542632, COSV100541474; called by muse, mutect2
- SACM1L | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs779832720, COSV66615269; called by muse, mutect2
- SALL1 | c.2686del p.D896Mfs*3 | Frame Shift Del (DEL) | VAF 24/196 reads (12%) | catalogued as COSV51757782; called by mutect2, varscan2
- SALL3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs372096716; called by muse, mutect2, varscan2
- SAMD11 | c.1714G>A p.G572R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370249951; called by muse, varscan2
- SAMD7 | c.20T>G p.L7W | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59418128; called by muse, mutect2
- SARM1 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.181); catalogued as rs782196355; called by muse, mutect2, varscan2
- SAT1 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100803872; called by muse, mutect2
- SBK3 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs780066497; called by muse, mutect2
- SC5D | c.39del p.F13Lfs*23 | Frame Shift Del (DEL) | VAF 43/250 reads (17%) | catalogued as rs1185907700; called by mutect2, pindel, varscan2
- SCRIB | c.4409G>A p.R1470Q | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782207419; called by muse, mutect2, varscan2
- SDC2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1418143004, COSV100143446; called by muse, mutect2, varscan2
- SEC14L5 | c.1863del p.S622Afs*14 | Frame Shift Del (DEL) | VAF 77/410 reads (19%) | catalogued as rs764657044; called by mutect2, pindel, varscan2
- SEMA5B | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs1453247310; called by muse, mutect2
- SERPINA6 | c.544del p.I182Lfs*48 | Frame Shift Del (DEL) | VAF 50/418 reads (12%) | catalogued as rs1566728222; called by mutect2, pindel, varscan2
- SERPINB8 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54639999; called by muse, mutect2, varscan2
- SF3B1 | c.2440T>C p.F814L | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59205889; called by muse, mutect2
- SH2D5 | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as rs745423162, COSV66707247; called by muse, mutect2, varscan2
- SH3BP4 | c.2572C>T p.R858W | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166061444; called by muse, mutect2, varscan2
- SH3KBP1 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs776018734; called by muse, mutect2, varscan2
- SHANK1 | c.6233C>T p.P2078L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1347899350, COSV53247342, COSV53257369; called by muse, mutect2, varscan2
- SHISA7 | c.1385del p.P462Qfs*75 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | catalogued as rs1234226395; called by mutect2, pindel, varscan2
- SHPK | c.1355T>C p.M452T | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1467038947; called by muse, mutect2, varscan2
- SIAH1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV99589424; called by muse, mutect2
- SIGLEC9 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs757055444, COSV51585638; called by muse, mutect2, varscan2
- SLC12A9 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs901050672, COSV51938443; called by muse, mutect2, varscan2
- SLC1A6 | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs757668994, COSV55668685; called by muse, mutect2
- SLC25A41 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs986273099; called by muse, mutect2, varscan2
- SLC25A53 | c.707T>C p.V236A | Missense Mutation (SNP) | VAF 52/423 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs1556354694; called by muse, mutect2, varscan2
- SLC26A6 | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1434645707; called by muse, varscan2
- SLC27A3 | c.1963G>A p.G655R (on ENST00000271857; = p.G527R on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55166448; called by muse, mutect2, varscan2
- SLC46A2 | c.1196T>C p.I399T | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs771543305; called by muse, mutect2, varscan2
- SLC46A2 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs891511859; called by muse, varscan2
- SLC4A11 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 74/489 reads (15%) | catalogued as rs1362719565, COSV66261027; called by muse, mutect2, varscan2
- SLC52A1 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs1251468579; called by muse, mutect2, varscan2
- SLC5A11 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 92/673 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374864110; called by muse, mutect2, varscan2
- SLC6A5 | c.1043T>C p.M348T | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs368513146; called by muse, mutect2
- SLC8A2 | c.2744A>G p.Y915C | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52639623; called by muse, mutect2, varscan2
- SLFN14 | c.807del p.E270Kfs*6 | Frame Shift Del (DEL) | VAF 30/225 reads (13%) | catalogued as rs757176140; called by mutect2, pindel, varscan2
- SLITRK1 | c.378del p.L127Wfs*19 | Frame Shift Del (DEL) | VAF 66/502 reads (13%) | catalogued as COSV65676819; called by mutect2, pindel, varscan2
- SMAD6 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763230117, COSV99993982; called by muse, mutect2, varscan2
- SMYD1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.131); catalogued as rs368175367, COSV70225850; called by muse, mutect2, varscan2
- SMYD3 | c.1085del p.F362Sfs*12 (on ENST00000490107 / NM_001375962.1; = p.F303Sfs*12 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/155 reads (12%) | catalogued as COSV63628704; called by mutect2, pindel, varscan2
- SORCS1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as rs1262994826, COSV99544071; called by muse, mutect2
- SPATA18 | c.1249A>G p.S417G | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV54649793; called by muse, mutect2
- SPATA32 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 75/558 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544166142; called by muse, mutect2, varscan2
- SPCS3 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV101543696; called by muse, mutect2
- SPG7 | c.1025G>C p.G342A (on ENST00000268704; = p.G349A on NM_003119.4) | Missense Mutation (SNP) | VAF 47/399 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387985266; called by mutect2, varscan2
- SRCAP | c.6452G>A p.R2151H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1247583725, COSV52667363; called by muse, mutect2, varscan2
- SRRM2 | c.3281C>A p.P1094H | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as rs1178885696; called by muse, mutect2
- ST8SIA2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 58/410 reads (14%) | PolyPhen benign (0.054); catalogued as rs533314466, COSV51572468; called by muse, mutect2, varscan2
- STEAP2 | c.733_734del p.S245* | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs1351494978; called by pindel, varscan2
- STRADA | c.448A>G p.M150V (on ENST00000336174 / NM_001363786.1; = p.M113V on NM_153335.6) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1477833021; called by muse, mutect2, varscan2
- STRIP1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs762658503; called by muse, mutect2, varscan2
- SUFU | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.151); catalogued as rs199673680, COSV64015852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | catalogued as rs770033147; called by mutect2, varscan2
- SYNGAP1 | c.3254G>A p.R1085Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs866807569; called by muse, mutect2, varscan2
- TACC2 | c.2347del p.Q783Rfs*32 | Frame Shift Del (DEL) | VAF 44/265 reads (17%) | catalogued as rs750901207; called by mutect2, pindel, varscan2
- TACR3 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 109/663 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761830661; called by muse, mutect2, varscan2
- TAFA5 | c.206C>T p.A69V (on ENST00000402357 / NM_001082967.3; = p.A62V on NM_015381.7) | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs929430715, COSV60981425; called by muse, mutect2, varscan2
- TAOK1 | c.2696C>T p.A899V | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as rs914788894; called by muse, mutect2, varscan2
- TBC1D21 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs771245536, COSV55997098; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 44/396 reads (11%) | catalogued as rs751224053; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 28/183 reads (15%) | catalogued as rs763321097; called by mutect2, varscan2
- TEKT3 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777321677; called by muse, mutect2, varscan2
- TESC | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1461691193; called by muse, mutect2
- TGFBR3 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs865949914; called by muse, mutect2
- TGM1 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 82/530 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs138574046; called by muse, mutect2, varscan2
- TGM2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs1425299786; called by muse, mutect2
- THBS3 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1428877193, COSV57425618; called by muse, mutect2
- THEMIS | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV64072754; called by muse, mutect2, varscan2
- TICRR | c.4862A>G p.Y1621C | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs1163361008, COSV51542945; called by muse, mutect2, varscan2
- TKFC | c.304+2T>C p.X102_splice | Splice Site (SNP) | VAF 28/234 reads (12%) | catalogued as rs1469624473; called by muse, mutect2, varscan2
- TLN2 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968813596; called by muse, mutect2, varscan2
- TLR6 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.211); catalogued as COSV67935064; called by muse, mutect2, varscan2
- TLR6 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs1467506737; called by muse, mutect2, varscan2
- TMEM175 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 66/376 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs375719692; called by muse, mutect2, varscan2
- TMEM214 | c.650A>G p.H217R | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs761098405, COSV99476588; called by muse, mutect2, varscan2
- TMEM239 | c.166G>A p.G56R (on ENST00000361033 / NM_001318207.1; = p.G13R on NM_001167670.3) | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1345004554; called by muse, mutect2, varscan2
- TMPRSS6 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 63/561 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1429658424; called by muse, mutect2, varscan2
- TNFAIP2 | c.930dup p.R311Qfs*14 | Frame Shift Ins (INS) | VAF 41/326 reads (13%) | catalogued as rs774638550; called by mutect2, pindel, varscan2
- TNFAIP3 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs774778736; called by muse, mutect2, varscan2
- TNFRSF13C | c.149G>A p.S50N | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs997496855; called by muse, mutect2, varscan2
- TNRC18 | c.2522del p.G841Afs*32 | Frame Shift Del (DEL) | VAF 47/348 reads (14%) | catalogued as rs1243889246; called by mutect2, pindel, varscan2
- TNXB | c.10049C>T p.A3350V (on ENST00000647633; = p.A3103V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/746 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as rs200191925; called by muse, mutect2
- TOP1MT | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462430247; called by muse, mutect2, varscan2
- TOPAZ1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs1371718823, COSV59075212; called by muse, mutect2
- TP73 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs574845163, COSV60705726; called by muse, mutect2, varscan2
- TPST1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 38/417 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1433304876, COSV59180596; called by muse, mutect2
- TRA2A | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs1297666144; called by muse, mutect2, varscan2
- TRAP1 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149684919; called by muse, mutect2, varscan2
- TREX2 | c.671G>A p.R224Q (on ENST00000334497; = p.R181Q on NM_080701.3) | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1556979259; called by muse, mutect2, varscan2
- TREX2 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57851386; called by muse, mutect2, varscan2
- TRIM7 | c.512A>G p.Q171R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1483545738; called by muse, mutect2, varscan2
- TRMT44 | c.1494+2T>C p.X498_splice | Splice Site (SNP) | VAF 8/62 reads (13%) | catalogued as rs1448016544; called by muse, varscan2
- TRPV2 | c.1329del p.I444Sfs*23 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | catalogued as COSV100641106; called by mutect2, pindel, varscan2
- TSPAN13 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.992); catalogued as rs934100301; called by muse, mutect2
- TTC13 | c.1339del p.T448Rfs*25 | Frame Shift Del (DEL) | VAF 17/140 reads (12%) | catalogued as rs867367503; called by mutect2, pindel
- TTC21A | c.3900C>A p.H1300Q | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs745585550; called by muse, varscan2
- TTC26 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1381828442; called by muse, mutect2, varscan2
- TTLL8 | c.2410del p.R804Efs*? | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs1392838945; called by mutect2, pindel
- TTN | c.72172C>T p.P24058S (on ENST00000591111; = p.P16634S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | PolyPhen probably damaging (0.999); catalogued as rs1435124022; called by muse, mutect2, varscan2
- TUBB4A | c.851T>C p.L284P | Missense Mutation (SNP) | VAF 92/785 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV51159012; called by muse, mutect2, varscan2
- TUBGCP2 | c.2668C>G p.P890A | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV53302823, COSV53306377; called by muse, mutect2, varscan2
- TUBGCP3 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.94); catalogued as rs1469395874; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs760251146; called by mutect2, varscan2
- TVP23A | c.110del p.F37Sfs*7 | Frame Shift Del (DEL) | VAF 25/193 reads (13%) | catalogued as rs758470373; called by mutect2, pindel, varscan2
- TWF1 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV57300669; called by muse, mutect2, varscan2
- TYK2 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748101413; called by muse, mutect2, varscan2
- TYW3 | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1384238200; called by muse, mutect2
- UBR3 | c.4990C>A p.L1664I | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV55849669; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs774161694, COSV51953966; called by muse, mutect2
- UHRF1BP1 | c.4055T>C p.L1352P | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1455724390; called by muse, mutect2, varscan2
- UMOD | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 51/439 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322587342; called by muse, mutect2, varscan2
- UNC79 | c.1411C>T p.R471W (on ENST00000393151 / NM_001346218.2; = p.R294W on NM_020818.5) | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV56418190; called by muse, mutect2, varscan2
- UNC80 | c.2873C>T p.A958V | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1288205911, COSV55883291; called by muse, mutect2, varscan2
- UNC80 | c.3820G>A p.A1274T | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs1340491003; called by muse, mutect2
- USP13 | c.269T>C p.M90T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV55871698; called by muse, mutect2, varscan2
- USP20 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs201314690; called by muse, mutect2, varscan2
- USP6NL | c.1890del p.S631Pfs*34 | Frame Shift Del (DEL) | VAF 53/349 reads (15%) | catalogued as rs760283281; called by mutect2, pindel, varscan2
- VLDLR | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 73/794 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.099); catalogued as rs748580464, COSV66073392; called by muse, mutect2
- VSIG10 | c.1016del p.P339Lfs*7 | Frame Shift Del (DEL) | VAF 9/103 reads (9%) | catalogued as rs772031843; called by mutect2, pindel
- VSTM4 | c.322dup p.A108Gfs*53 (on ENST00000332853 / NM_001031746.5; = p.A108Gfs*87 on NM_144984.4) | Frame Shift Ins (INS) | VAF 32/353 reads (9%) | catalogued as rs781660756; called by mutect2, pindel
- VWA7 | c.574_576del p.L192del | In Frame Del (DEL) | VAF 30/236 reads (13%) | catalogued as rs1175242018; called by pindel, varscan2
- VWDE | c.4252G>T p.G1418* | Nonsense Mutation (SNP) | VAF 12/191 reads (6%) | catalogued as COSV99281239; called by muse, mutect2
- VWF | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 54/470 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1022679972, COSV54611681; called by muse, varscan2
- WASHC2C | c.3166G>A p.A1056T (on ENST00000336378; = p.A1035T on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/1100 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1554891413; called by muse, mutect2
- WDPCP | c.255A>G p.S85= | Splice Region (SNP) | VAF 54/388 reads (14%) | catalogued as rs1252079324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR27 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs368374418; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR74 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.816); catalogued as rs762151988; called by muse, mutect2, varscan2
- WNT6 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 48/338 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.59); catalogued as rs1310349406; called by muse, mutect2, varscan2
- WNT7A | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53202786; called by muse, mutect2, varscan2
- WRAP73 | c.1261C>G p.L421V | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV54561304; called by muse, mutect2, varscan2
- WT1 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 66/569 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV60067246; called by muse, mutect2, varscan2
- XKR9 | c.458T>C p.I153T | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs758504730; called by muse, mutect2
- XYLT2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 67/478 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs763464424; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 48/446 reads (11%) | catalogued as rs779864368; called by mutect2, varscan2
- YIF1A | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748324051; called by muse, mutect2, varscan2
- YRDC | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763156645; called by muse, mutect2, varscan2
- YWHAZ | c.722_724del p.E241del | In Frame Del (DEL) | VAF 26/262 reads (10%) | catalogued as rs1183225998; called by pindel, varscan2
- ZACN | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs144136649; called by muse, mutect2, varscan2
- ZBTB4 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.125); catalogued as rs569544436; called by muse, mutect2, varscan2
- ZBTB48 | c.1780C>T p.R594W | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs752758479; called by muse, mutect2
- ZC3H13 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs768523970; called by muse, mutect2, varscan2
- ZDHHC8 | c.1368del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 11/104 reads (11%) | catalogued as rs752072853; called by pindel, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | catalogued as rs781677398, COSV57709922; called by pindel, varscan2
- ZEB2 | c.1220A>G p.H407R | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as rs757875316; called by muse, mutect2, varscan2
- ZFHX3 | c.10215del p.A3407Lfs*78 | Frame Shift Del (DEL) | VAF 23/185 reads (12%) | catalogued as rs762108866; called by mutect2, pindel, varscan2
- ZFHX3 | c.1388C>A p.A463E | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs527536496, COSV99215508; called by muse, mutect2
- ZFP42 | c.766T>C p.F256L | Missense Mutation (SNP) | VAF 64/403 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1275751414; called by muse, mutect2, varscan2
- ZMAT1 | c.368G>A p.C123Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV65658697; called by mutect2, varscan2
- ZMAT3 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.156); catalogued as rs1386591481, COSV100265069; called by muse, mutect2
- ZMYND8 | c.3386C>T p.T1129M (on ENST00000311275 / NM_001363741.2; = p.T1103M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs774218893; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as COSV61506988; called by pindel, varscan2
- ZNF248 | c.1337G>C p.C446S | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.074); catalogued as COSV61998198; called by muse, mutect2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 22/178 reads (12%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF416 | c.783_784del p.R262Sfs*9 | Frame Shift Del (DEL) | VAF 34/273 reads (12%) | catalogued as rs1438615878; called by mutect2, pindel, varscan2
- ZNF500 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs752694669; called by muse, mutect2, varscan2
- ZNF516 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs1433387964; called by muse, mutect2, varscan2
- ZNF521 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.407); catalogued as rs775684318, COSV64129492, COSV64129502; called by muse, mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 29/203 reads (14%) | catalogued as rs1249713061; called by mutect2, pindel, varscan2
- ZNF540 | c.445del p.M149Cfs*12 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as COSV100329754, COSV57108094; called by mutect2, pindel, varscan2
- ZNF560 | c.2270A>G p.Q757R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs760553564; called by muse, mutect2, varscan2
- ZNF579 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs757346763; called by muse, mutect2, varscan2
- ZNF594 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 59/390 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1440464175; called by muse, mutect2, varscan2
- ZNF598 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 53/422 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1171000889; called by muse, mutect2, varscan2
- ZNF660 | c.564del p.V189Ffs*41 | Frame Shift Del (DEL) | VAF 32/247 reads (13%) | catalogued as rs1223044543; called by mutect2, pindel, varscan2
- ZNF775 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 77/453 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as rs1179907707, COSV100301385; called by muse, mutect2, varscan2
- ZNF844 | c.1461del p.P488Hfs*7 | Frame Shift Del (DEL) | VAF 32/222 reads (14%) | catalogued as rs1326181394; called by mutect2, pindel, varscan2
- ZSCAN5A | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1348062471; called by muse, mutect2
- ZSWIM6 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 42/283 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as rs191155035; called by muse, mutect2, varscan2
- ZSWIM8 | c.3961G>A p.A1321T (on ENST00000605216 / NM_001242487.2; = p.A1326T on NM_015037.3) | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs912997444, COSV55213040; called by muse, mutect2, varscan2
- ZXDA | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 9/222 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1217317442; called by muse, mutect2
- AADACL3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- AARS1 | c.1290A>C p.E430D | Missense Mutation (SNP) | VAF 54/799 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2
- AARS2 | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 30/570 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCA10 | c.4235T>C p.M1412T | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- ABCA2 | c.4714A>G p.T1572A (on ENST00000614293; = p.T1542A on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ABCA3 | c.4164+2T>C p.X1388_splice | Splice Site (SNP) | VAF 75/583 reads (13%) | called by muse, varscan2
- ABHD13 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- ABHD13 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, varscan2
- ABI1 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- ABT1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- AC004922.1 | c.706del p.S236Vfs*7 | Frame Shift Del (DEL) | VAF 22/200 reads (11%) | called by pindel, varscan2
- AC008397.2 | c.811A>G p.T271A | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACACA | c.2585A>G p.K862R | Missense Mutation (SNP) | VAF 62/500 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACP6 | c.220-1G>T p.X74_splice | Splice Site (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- ACTR6 | c.942del p.F314Lfs*6 | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- ADAM29 | c.1426C>A p.P476T | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS9 | c.5061dup p.S1688Efs*21 | Frame Shift Ins (INS) | VAF 6/57 reads (11%) | called by mutect2, pindel, varscan2
- ADARB2 | c.804del p.A269Pfs*15 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- ADCY4 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADCY9 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 47/217 reads (22%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4505dup p.L1503Afs*195 | Frame Shift Ins (INS) | VAF 67/395 reads (17%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.2780T>A p.L927H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADRA1B | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ADRA1D | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 33/564 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- AGBL5 | c.1535+1G>T p.X512_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | called by muse, varscan2
- AGTPBP1 | c.1600T>G p.L534V (on ENST00000357081 / NM_001330701.2; = p.L494V on NM_015239.2) | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- AKAP3 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ALDH1L2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG8 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALOX15B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AMH | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 98/690 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AMH | c.1609A>G p.I537V | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); called by muse, mutect2
- AMPD3 | c.1136G>A p.G379D (on ENST00000396553 / NM_001025389.2; = p.G388D on NM_000480.3) | Missense Mutation (SNP) | VAF 84/535 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMPH | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ANKK1 | c.2105A>C p.K702T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2
- ANKRD17 | c.44_46del p.E15del | In Frame Del (DEL) | VAF 24/270 reads (9%) | called by mutect2, pindel
- ANKRD30B | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ANKRD36C | c.4962del p.K1654Nfs*13 | Frame Shift Del (DEL) | VAF 17/116 reads (15%) | called by mutect2, varscan2
- ANKRD9 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ANKS1A | c.1803T>G p.S601R | Missense Mutation (SNP) | VAF 49/410 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ANKS1B | c.3075C>G p.D1025E (on ENST00000547776 / NM_152788.4; = p.D191E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AOC1 | c.1618A>G p.T540A | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- APC2 | c.5402C>A p.P1801H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- APOB | c.9632dup p.N3211Kfs*14 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | called by mutect2, varscan2
- ARHGAP20 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGAP22 | c.2044del p.S682Rfs*3 | Frame Shift Del (DEL) | VAF 34/400 reads (9%) | called by mutect2, pindel
- ARHGAP27 | c.2045A>G p.Q682R (on ENST00000428638 / NM_001282290.1; = p.Q341R on NM_199282.3) | Missense Mutation (SNP) | VAF 79/529 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ARHGAP40 | c.492dup p.L165Afs*82 | Frame Shift Ins (INS) | VAF 26/222 reads (12%) | called by mutect2, pindel, varscan2
- ARHGEF11 | c.3206+1G>A p.X1069_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF17 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF37 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 53/485 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ARID1A | c.572del p.G191Afs*41 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- ARID2 | c.4309G>A p.A1437T | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ART1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- ASAP1 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATAD2 | c.4033C>T p.Q1345* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- ATF1 | c.359T>C p.L120S | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- ATF4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2
- ATP13A4 | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ATP9A | c.545del p.N182Tfs*71 | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 40/199 reads (20%) | called by mutect2, varscan2
- ATXN7 | c.2340del p.T781Pfs*11 | Frame Shift Del (DEL) | VAF 32/235 reads (14%) | called by mutect2, varscan2
- B3GALNT1 | c.301T>C p.W101R | Missense Mutation (SNP) | VAF 50/353 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B4GALNT4 | c.295dup p.A99Gfs*29 | Frame Shift Ins (INS) | VAF 40/304 reads (13%) | called by mutect2, varscan2
- BAHCC1 | c.2606A>G p.D869G | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by mutect2, varscan2
- BAIAP3 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 69/530 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- BAZ1A | c.219del p.A74Qfs*12 | Frame Shift Del (DEL) | VAF 29/224 reads (13%) | called by mutect2, varscan2
- BBS7 | c.397T>C p.C133R | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
1,513 further variants in this file (760 protein-altering or splice-affecting, 483 silent, 270 other) are not listed here.
